Somatic mutation profile of tumor specimen TCGA-AC-A7VC-01A (aliquot TCGA-AC-A7VC-01A-11D-A351-09) from TCGA case TCGA-AC-A7VC, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Metaplastic carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 56.1 years (20,479 days).
Specimen TCGA-AC-A7VC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3cfe0ae4-7b10-4583-8206-098c29088e92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A7VC-10A (Blood Derived Normal), aliquot TCGA-AC-A7VC-10A-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8e38602-d114-4641-a2bb-6921ae7cfc57

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 11, Silent 4, Nonsense Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1147C>T p.Q383* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as rs1131690846, CM030502, COSV57312613, COSV57322161; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 21/27 reads (78%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACP3 | c.986T>C p.M329T | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100313440; called by muse, mutect2
- CSMD3 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV52186797, COSV99838547; called by muse, mutect2, varscan2
- GALE | c.1033G>A p.G345S | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100994802; called by muse, mutect2
- HDLBP | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV100191162; called by muse, mutect2, varscan2
- KMT2D | c.4473G>A p.W1491* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV99981652; called by muse, mutect2, varscan2
- PLXNC1 | c.3726A>C p.L1242F | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.21); catalogued as COSV99313394; called by muse, mutect2, varscan2
- POLR3E | c.1504G>T p.V502L | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs756072532, COSV100242226; called by muse, mutect2, varscan2
- TRIM2 | c.149A>G p.Y50C (on ENST00000437508; = p.Y77C on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100108045; called by muse, mutect2, varscan2
- XPR1 | c.926G>A p.S309N | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100851488; called by muse, mutect2, varscan2
- ADGRA3 | c.891C>A p.N297K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2
- CSAG3 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 67/242 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MED12 | c.111_128delinsCAT p.A38_Q43delinsI | In Frame Del (DEL) | VAF 43/74 reads (58%) | called by pindel, varscan2*
- CYB5R4 | c.66G>C p.G22= | Silent (SNP) | VAF 64/160 reads (40%) | catalogued as COSV100859446, COSV100859519, COSV63747409; called by muse, mutect2, varscan2
- PCDHB2 | c.657C>T p.G219= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV52035339, COSV52036061; called by muse, mutect2, varscan2
- SLC9A8 | c.1593C>T p.D531= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs375508701; called by muse, mutect2, varscan2
- ZC3HAV1 | c.630C>T p.D210= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as rs149165464; called by muse, mutect2, varscan2
